Somatic mutation profile of tumor specimen TCGA-AP-A1DK-01A (aliquot TCGA-AP-A1DK-01A-11D-A135-09) from TCGA case TCGA-AP-A1DK, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 53.4 years (19,509 days).
Specimen TCGA-AP-A1DK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e0519e7-1fa4-4ffe-93cc-5697e12e8a3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A1DK-10A (Blood Derived Normal), aliquot TCGA-AP-A1DK-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0702253c-6de7-4986-9df4-faba66f9af0d

The open-access MAF lists 13,189 somatic variants for this specimen: 9,200 protein-altering or splice-affecting, 3,720 silent, 269 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8,072, Silent 3,720, Nonsense Mutation 494, Splice Site 285, Splice Region 132, Intron 110, Frame Shift Ins 100, Frame Shift Del 80, RNA 72, 3'UTR 30, 5'UTR 25, Translation Start Site 18.

Variants (750 of 13,189; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.2041C>T p.R681* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as rs61749423, CM990029; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ATP1A3 | c.1163G>A p.R388H (on ENST00000545399 / NM_001256214.2; = p.R375H on NM_152296.5) | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs200891944, COSV57486868; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- B2M | c.68-2A>G p.X23_splice | Splice Site (SNP) | VAF 12/30 reads (40%) | hotspot (GDC flag); catalogued as rs111482205, COSV62562974, COSV62564351; called by muse, mutect2, varscan2
- BCL11B | c.721C>T p.Q241* (on ENST00000357195 / NM_001282237.2; = p.Q170* on NM_022898.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as rs1314314373; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CD40LG | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs104894768, CD972114, CM099773, CM960260; ClinVar: pathogenic; called by muse, varscan2
- CHEK2 | c.276dup p.W93Lfs*15 | Frame Shift Ins (INS) | VAF 13/43 reads (30%) | catalogued as rs876661156; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- CIC | c.4535G>A p.R1512H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50554672, COSV50623937; called by muse, mutect2, varscan2
- COL1A1 | c.1678G>A p.G560S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs67507747, CM900065, CM930144, CM962422, COSV56804476; ClinVar: pathogenic; called by mutect2, varscan2
- COL4A3 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as rs371334239, CM014040, COSV67417567; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CSRP3 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs142019584; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 9/29 reads (31%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- ERBB2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 19/75 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs1057519862, COSV54062926; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GFAP | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs59565950, CM010050, CM023922, CM067416, COSV53652317; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIF1A | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548204329; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- LAMP2 | c.973dup p.L325Pfs*25 | Frame Shift Ins (INS) | VAF 10/63 reads (16%) | catalogued as rs1556092459; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PHKA1 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as rs1556299510; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIP5K1C | c.1127+1G>A p.X376_splice | Splice Site (SNP) | VAF 16/46 reads (35%) | catalogued as rs1473218681; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PKHD1 | c.11695C>T p.Q3899* | Nonsense Mutation (SNP) | VAF 31/126 reads (25%) | catalogued as rs1295732689; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 49/81 reads (60%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- SBF2 | c.3586C>T p.R1196* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as rs120074138, CM031143; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.4016C>T p.A1339V (on ENST00000303395 / NM_001202435.3; = p.A1328V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs794726789, CM1211355; ClinVar: pathogenic; called by muse, mutect2
- SLC27A4 | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137853135, CM094910, COSV100307433; ClinVar: pathogenic; called by muse, mutect2, varscan2
- THOC6 | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs200426926; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TPP1 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750428882, CM1311262; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.49144C>T p.R16382* (on ENST00000591111; = p.R8958* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as rs1553682168, COSV59902742; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TULP1 | c.855dup p.V286Rfs*98 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | catalogued as rs1554125752; ClinVar: likely pathogenic; called by pindel, varscan2
- A1BG | c.1460C>A p.P487H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54053784; called by muse, mutect2, varscan2
- A1BG | c.398T>C p.L133P | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1334382918; called by muse, mutect2, varscan2
- A1BG | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756720797; called by muse, mutect2, varscan2
- A1CF | c.605-1G>A p.X202_splice | Splice Site (SNP) | VAF 8/48 reads (17%) | catalogued as COSV50970170; called by muse, mutect2
- A2ML1 | c.1845G>A p.M615I | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1256253601; called by muse, mutect2, varscan2
- A2ML1 | c.3698G>A p.G1233E | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100228565; called by muse, mutect2, varscan2
- AASDH | c.2599G>T p.G867* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as COSV52705468; called by muse, mutect2, varscan2
- AATK | c.409G>T p.G137W (on ENST00000326724 / NM_001080395.3; = p.G34W on NM_004920.2) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99044987; called by muse, mutect2, varscan2
- ABAT | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1174585175, COSV51624298, COSV99076779; called by muse, mutect2, varscan2
- ABCA1 | c.3047C>T p.A1016V | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1189073138; called by muse, varscan2
- ABCA10 | c.1016G>A p.G339D | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.179); catalogued as rs1471545633; called by muse, mutect2, varscan2
- ABCA12 | c.7436G>A p.R2479K (on ENST00000272895 / NM_173076.3; = p.R2161K on NM_015657.3) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as CS071148, COSV99790198; called by muse, mutect2, varscan2
- ABCA12 | c.5848C>T p.R1950* (on ENST00000272895 / NM_173076.3; = p.R1632* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | catalogued as rs375437551, CM052165; called by muse, mutect2, varscan2
- ABCA12 | c.1061+1G>T p.X354_splice (on ENST00000272895 / NM_173076.3; = p.X36_splice on NM_015657.3) | Splice Site (SNP) | VAF 15/44 reads (34%) | catalogued as COSV55956443; called by muse, mutect2, varscan2
- ABCA13 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.744); catalogued as COSV70039510; called by muse, mutect2, varscan2
- ABCA4 | c.4868G>A p.G1623D | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM161726; called by muse, mutect2, varscan2
- ABCA6 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as COSV52638402; called by muse, mutect2
- ABCB1 | c.1345G>A p.G449R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55963240, COSV99713274; called by muse, mutect2, varscan2
- ABCB5 | c.803G>T p.R268M | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1457517086, COSV51703986; called by muse, mutect2, varscan2
- ABCB5 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs1422671115, COSV51708888; called by muse, mutect2, varscan2
- ABCB5 | c.3769C>T p.Q1257* (on ENST00000404938 / NM_001163941.2; = p.Q812* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as rs1196761668, COSV99329812; called by muse, mutect2
- ABCC1 | c.2326G>A p.V776M | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as rs763781150, COSV60693286; called by muse, mutect2, varscan2
- ABCC1 | c.3148G>A p.V1050M | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.074); catalogued as rs898683852; called by muse, mutect2, varscan2
- ABCC3 | c.2522G>A p.R841H | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs770775971; called by muse, mutect2, varscan2
- ABCC3 | c.3326C>A p.P1109Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs564256468, COSV99558656; called by muse, mutect2, varscan2
- ABCC4 | c.3469G>A p.E1157K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.217); catalogued as rs1415176622; called by muse, mutect2, varscan2
- ABCC5 | c.2484G>A p.G828= | Splice Region (SNP) | VAF 6/23 reads (26%) | catalogued as rs777031386; called by muse, mutect2, varscan2
- ABCC6 | c.3997G>A p.V1333M | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.249); catalogued as rs142505247; called by muse, mutect2, varscan2
- ABCC6 | c.1459C>T p.R487W | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374244303; called by muse, mutect2, varscan2
- ABCC8 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs1333862569; called by muse, mutect2, varscan2
- ABCC9 | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs749786076, COSV53966945; called by muse, mutect2, varscan2
- ABCD1 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.034); catalogued as CM105370; called by muse, mutect2, varscan2
- ABCD2 | c.836G>A p.G279D | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58052470; called by muse, mutect2, varscan2
- ABCE1 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56846602; called by muse, varscan2
- ABCG1 | c.541T>C p.S181P | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV100494503; called by muse, mutect2, varscan2
- ABCG4 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs776492089, COSV56642558; called by muse, mutect2, varscan2
- ABCG5 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53213715; called by muse, mutect2, varscan2
- ABHD1 | c.459-2A>G p.X153_splice | Splice Site (SNP) | VAF 8/22 reads (36%) | catalogued as COSV53208416; called by muse, mutect2, varscan2
- ABHD1 | c.1066G>T p.G356C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53207169; called by muse, mutect2, varscan2
- ABHD16B | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs1260956640, COSV99410895; called by muse, mutect2, varscan2
- ABHD16B | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs1479677682; called by muse, mutect2, varscan2
- ABI3 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs143540619; called by muse, mutect2, varscan2
- ABLIM2 | c.433C>T p.H145Y | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1199234703; called by muse, mutect2, varscan2
- ABTB2 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as rs1054275693; called by muse, mutect2, varscan2
- AC004593.2 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs765752880; called by muse, mutect2, varscan2
- AC004922.1 | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53162608; called by muse, mutect2, varscan2
- AC092143.1 | c.1218C>A p.Y406* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV100205914; called by muse, mutect2, varscan2
- AC097637.1 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs752555088; called by muse, mutect2, varscan2
- ACACB | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780343613, COSV100622914; called by muse, mutect2, varscan2
- ACADM | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.19); catalogued as rs141043231; called by muse, varscan2
- ACADM | c.600G>A p.W200* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as rs1553124735, CM136361; called by muse, mutect2, varscan2
- ACAT1 | c.886A>G p.M296V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as rs368802454; called by muse, mutect2, varscan2
- ACD | c.717G>A p.E239= (on ENST00000620338; = p.E150= on NM_022914.3) | Splice Region (SNP) | VAF 10/31 reads (32%) | catalogued as rs763160982; called by muse, mutect2, varscan2
- ACER1 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs763462645, COSV56836336; called by muse, mutect2, varscan2
- ACHE | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1366880550; called by muse, mutect2, varscan2
- ACKR2 | c.464T>C p.L155P | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as rs543451438, COSV56178987; called by muse, mutect2, varscan2
- ACLY | c.867C>T p.S289= | Splice Region (SNP) | VAF 12/41 reads (29%) | catalogued as rs1281001958, COSV61251349; called by muse, mutect2, varscan2
- ACOT2 | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1346583770; called by muse, mutect2, varscan2
- ACRV1 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as rs890717192; called by muse, mutect2, varscan2
- ACSF2 | c.370G>T p.G124C | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99366037; called by muse, mutect2, varscan2
- ACSF3 | c.197A>G p.H66R | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as rs1485054589; called by muse, mutect2, varscan2
- ACTL8 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs752015023; called by muse, mutect2, varscan2
- ACTL8 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as rs755110447, COSV64860446, COSV64862704; called by muse, mutect2, varscan2
- ACTR10 | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as COSV99580829; called by muse, mutect2, varscan2
- ACTR1A | c.590A>G p.Y197C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs756997769; called by mutect2, varscan2
- ACTR3B | c.756G>A p.W252* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as COSV55448290; called by muse, mutect2, varscan2
- ACTR3B | c.1034C>A p.A345D | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.124); catalogued as COSV55449592; called by muse, mutect2, varscan2
- ACTR5 | c.856G>A p.G286S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.21); catalogued as COSV54760252; called by muse, mutect2, varscan2
- ADA2 | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771067636; called by muse, mutect2, varscan2
- ADAM11 | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs780005911, COSV52345308; called by muse, mutect2
- ADAM18 | c.1861G>T p.G621* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV55856842; called by muse, mutect2
- ADAM19 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.597); catalogued as COSV57431452; called by muse, mutect2, varscan2
- ADAM22 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.268); catalogued as COSV55974173, COSV99716897; called by muse, mutect2, varscan2
- ADAM29 | c.726G>T p.K242N | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.051); catalogued as COSV63667576; called by muse, mutect2
- ADAM33 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.968); catalogued as rs1357707682, COSV100597743; called by muse, mutect2, varscan2
- ADAM9 | c.2168T>C p.L723P | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1178523538; called by muse, varscan2
- ADAMDEC1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs771273667, COSV99836025; called by muse, mutect2, varscan2
- ADAMDEC1 | c.910G>T p.D304Y | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99835912; called by muse, mutect2, varscan2
- ADAMTS10 | c.2617C>T p.P873S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.682); catalogued as COSV54353893; called by muse, mutect2, varscan2
- ADAMTS10 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.456); catalogued as COSV99546321; called by muse, mutect2, varscan2
- ADAMTS13 | c.1732C>T p.P578S | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.506); catalogued as rs967004764; called by muse, mutect2
- ADAMTS14 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs376783762; called by mutect2, varscan2
- ADAMTS14 | c.2940C>T p.C980= | Splice Region (SNP) | VAF 12/44 reads (27%) | catalogued as rs141787726, COSV64601076; called by muse, mutect2, varscan2
- ADAMTS14 | c.3439C>T p.R1147* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as rs769479026; called by muse, mutect2, varscan2
- ADAMTS18 | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1018687209, COSV51398590; called by muse, mutect2, varscan2
- ADAMTS2 | c.2599T>C p.S867P | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs372242497; called by muse, mutect2, varscan2
- ADAMTS2 | c.2293G>A p.V765I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.041); catalogued as rs777314559, COSV52364820; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS2 | c.2074G>A p.G692R | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs1427715074; called by muse, mutect2, varscan2
- ADAMTS3 | c.3565G>A p.G1189R | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.073); catalogued as COSV54393799; called by muse, mutect2, varscan2
- ADAMTS3 | c.1259C>A p.A420D | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.944); catalogued as rs188897708, COSV54400247; called by muse, mutect2, varscan2
- ADAMTS3 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV54402511; called by muse, mutect2, varscan2
- ADAMTS5 | c.2584G>A p.V862I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs775381325, COSV53184091; called by muse, mutect2, varscan2
- ADAMTS9 | c.5027C>A p.P1676H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.94); catalogued as COSV55776780; called by muse, mutect2, varscan2
- ADAMTSL5 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as rs1242594585; called by muse, mutect2, varscan2
- ADAR | c.3001C>T p.R1001C | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM146510; called by muse, mutect2, varscan2
- ADARB1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1569120275; called by muse, varscan2
- ADCY1 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs898381045; called by muse, mutect2, varscan2
- ADCY8 | c.2975C>T p.A992V | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as rs770559183, COSV53896037, COSV53906569; called by muse, mutect2, varscan2
- ADCY9 | c.2252G>A p.S751N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1229246853; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.176A>G p.D59G | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58441116; called by muse, mutect2, varscan2
- ADD2 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.327); catalogued as rs1327135861, COSV100036769, COSV52464540; called by muse, mutect2, varscan2
- ADGRA1 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as rs1295114236, COSV63416430; called by muse, mutect2, varscan2
- ADGRB2 | c.3552G>T p.Q1184H | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57072973; called by muse, mutect2, varscan2
- ADGRE5 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.738); catalogued as rs376892799; called by muse, mutect2, varscan2
- ADGRF2 | c.430A>T p.T144S (on ENST00000296862 / NM_001368115.2; = p.T76S on NM_153839.7) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.143); catalogued as rs1329020846; called by muse, mutect2, varscan2
- ADGRF2 | c.1618G>A p.A540T (on ENST00000296862 / NM_001368115.2; = p.A472T on NM_153839.7) | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1363080513; called by muse, mutect2, varscan2
- ADGRG4 | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV99795069; called by muse, mutect2, varscan2
- ADGRG4 | c.1700G>T p.G567V | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV99794621; called by muse, mutect2, varscan2
- ADGRG4 | c.5890A>G p.I1964V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs181533402, COSV54964965; called by muse, mutect2, varscan2
- ADGRG5 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV61082603; called by muse, mutect2, varscan2
- ADGRG6 | c.2677C>T p.R893* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as rs749312742, COSV51594514; called by muse, mutect2, varscan2
- ADGRV1 | c.11827C>T p.R3943W | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762677981, COSV67996847; called by muse, mutect2, varscan2
- ADH4 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.189); catalogued as rs200208857; called by mutect2, varscan2
- ADNP | c.1981A>G p.T661A | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.038); catalogued as COSV62424479; called by muse, mutect2, varscan2
- ADNP2 | c.1592T>C p.V531A | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1279513435; called by muse, mutect2, varscan2
- ADRB2 | c.1178C>A p.T393N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.216); catalogued as rs1183743240; called by muse, mutect2, varscan2
- ADRM1 | c.556C>A p.L186M | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.554); catalogued as COSV99439321; called by muse, mutect2, varscan2
- AFF1 | c.1400G>A p.S467N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as COSV57119972, COSV57125070; called by muse, mutect2, varscan2
- AFM | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs767212648, COSV56919099; called by muse, varscan2
- AGAP2 | c.2020C>T p.R674* (on ENST00000547588 / NM_001122772.2; = p.R338* on NM_014770.4) | Nonsense Mutation (SNP) | VAF 25/96 reads (26%) | catalogued as rs1555198771; called by muse, mutect2, varscan2
- AGAP3 | c.1526C>T p.T509I (on ENST00000622464; = p.T545I on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1293522357; called by muse, mutect2, varscan2
- AGAP3 | c.2480G>A p.R827H (on ENST00000622464; = p.R863H on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.523); catalogued as rs750134704, COSV52547201; called by muse, mutect2, varscan2
- AGBL1 | c.1315T>C p.Y439H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV101222533; called by muse, mutect2
- AGBL1 | c.2816G>A p.R939K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs774199770, COSV66870195; called by muse, mutect2, varscan2
- AGBL2 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV54094237; called by muse, mutect2, varscan2
- AGFG2 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs375268704, COSV53544055; called by muse, mutect2, varscan2
- AGK | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs150893768; called by muse, mutect2, varscan2
- AGO1 | c.2414G>A p.R805H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1365053413; called by mutect2, varscan2
- AGR2 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs755871634, COSV68596667; called by muse, mutect2, varscan2
- AGTPBP1 | c.1805A>G p.D602G (on ENST00000357081 / NM_001330701.2; = p.D562G on NM_015239.2) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs757881223; called by muse, mutect2, varscan2
- AHCYL1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs756700510, COSV100779447; called by muse, varscan2
- AHI1 | c.2961A>G p.T987= | Splice Region (SNP) | VAF 10/34 reads (29%) | catalogued as rs753351221; called by muse, mutect2, varscan2
- AHNAK | c.17393C>T p.T5798M | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs755582094; called by muse, mutect2, varscan2
- AHNAK | c.9066G>A p.M3022I | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.758); catalogued as rs1332346661; called by muse, mutect2, varscan2
- AHNAK | c.4003C>T p.P1335S | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1335627736; called by muse, mutect2, varscan2
- AHNAK | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57205398; called by muse, mutect2, varscan2
- AHR | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54126014; called by muse, mutect2, varscan2
- AIF1L | c.398G>A p.S133N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs760118169; called by muse, varscan2
- AIFM3 | c.357C>T p.G119= | Splice Region (SNP) | VAF 13/29 reads (45%) | catalogued as rs542222592; called by muse, mutect2, varscan2
- AIFM3 | c.971A>G p.N324S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.475); catalogued as rs754639841; called by mutect2, varscan2
- AIFM3 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as rs778803055; called by muse, varscan2
- AIM2 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1469414121; called by muse, mutect2, varscan2
- AK2 | c.242A>G p.D81G (on ENST00000354858; = p.D123G on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs770292274; called by muse, mutect2, varscan2
- AKAP11 | c.5158A>G p.S1720G | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs555059217; called by muse, mutect2, varscan2
- AKAP12 | c.2846C>T p.T949M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as rs766910226, COSV53572564; called by muse, mutect2, varscan2
- AKAP13 | c.1165G>A p.V389M | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs770701124, COSV63466275; called by muse, mutect2, varscan2
- AKAP13 | c.2155T>C p.S719P | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); catalogued as rs1438605183; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKR1A1 | c.752+1G>A p.X251_splice | Splice Site (SNP) | VAF 18/58 reads (31%) | catalogued as rs932805777; called by muse, mutect2, varscan2
- AKT3 | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs1230714185; called by muse, mutect2, varscan2
- AL031315.1 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as rs750401117, COSV61212236; called by muse, mutect2, varscan2
- AL031681.2 | c.3101A>G p.H1034R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.538); catalogued as rs1189334958, COSV100916885; called by muse, mutect2, varscan2
- AL035461.3 | c.2784A>G p.P928= | Splice Region (SNP) | VAF 9/40 reads (23%) | catalogued as rs1266123396; called by muse, mutect2, varscan2
- AL121899.2 | c.98C>A p.A33D | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs749279971; called by muse, mutect2, varscan2
- AL441992.2 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1309303171; called by muse, mutect2, varscan2
- ALAS2 | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as COSV58191192; called by muse, mutect2, varscan2
- ALB | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0.021); catalogued as COSV55737884, COSV55741637; called by muse, mutect2, varscan2
- ALDH18A1 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64663458; called by muse, mutect2, varscan2
- ALDH1A3 | c.345C>T p.A115= | Splice Region (SNP) | VAF 22/81 reads (27%) | catalogued as rs1284970733; called by muse, mutect2, varscan2
- ALDH2 | c.395T>C p.V132A | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs759512257; called by muse, mutect2, varscan2
- ALDH3B1 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as rs555112533; called by muse, mutect2, varscan2
- ALDH3B1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1003063966, COSV50291733; called by muse, mutect2, varscan2
- ALG10B | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771614193; called by muse, mutect2, varscan2
- ALG12 | c.1363G>A p.V455M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | PolyPhen benign (0.006); catalogued as rs367671008; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALG13 | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767153325, COSV52634625, COSV99322475; called by muse, mutect2, varscan2
- ALG13 | c.3260C>T p.P1087L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV52643592; called by muse, mutect2, varscan2
- ALG1L | c.549G>T p.Q183H | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs1345093967; called by muse, mutect2, varscan2
- ALG8 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.082); catalogued as rs745537692; called by muse, mutect2, varscan2
- ALK | c.2194G>A p.D732N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs768366852, COSV66562209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALKBH1 | c.587T>C p.L196P | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53660965; called by muse, mutect2, varscan2
- ALKBH5 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs760405725, COSV67686916; called by muse, varscan2
- ALOX12B | c.1071G>A p.Q357= | Splice Region (SNP) | VAF 13/48 reads (27%) | catalogued as CM162706; called by muse, mutect2, varscan2
- ALOX5 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs551364951, COSV65551176; called by muse, mutect2, varscan2
- ALPG | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1257566433; called by muse, mutect2, varscan2
- ALPK2 | c.4881G>A p.M1627I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64493213; called by muse, mutect2, varscan2
- ALS2 | c.3518A>G p.E1173G | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV51891912, COSV99969801; called by muse, mutect2, varscan2
- ALS2CL | c.1783G>A p.V595M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs375839639; called by muse, mutect2, varscan2
- ALS2CL | c.1382G>A p.G461D | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769893213; called by muse, varscan2
- AMBRA1 | c.1042C>T p.P348S (on ENST00000458649 / NM_001367468.1; = p.P258S on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as COSV54051594; called by muse, varscan2
- AMER1 | c.1408G>T p.G470C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57670815; called by muse, varscan2
- AMFR | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs779952471, COSV51922629; called by muse, mutect2, varscan2
- AMHR2 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as rs746905091, COSV57686437; called by muse, mutect2, varscan2
- AMOTL2 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as rs1193686739; called by muse, mutect2, varscan2
- ANAPC5 | c.1486C>T p.R496* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as rs1434842906; called by mutect2, varscan2
- ANAPC5 | c.85T>C p.W29R | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs1279848074; called by muse, mutect2, varscan2
- ANGPT4 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV101124830, COSV67921490; called by muse, mutect2, varscan2
- ANK2 | c.5723G>A p.G1908D | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.572); catalogued as COSV52168802; called by muse, mutect2, varscan2
- ANK3 | c.2980G>T p.G994W (on ENST00000280772 / NM_001320874.2; = p.G128W on NM_001149.3) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55055058; called by muse, varscan2
- ANKAR | c.2715G>A p.M905I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1374500588; called by muse, mutect2, varscan2
- ANKFN1 | c.1316+1G>A p.X439_splice | Splice Site (SNP) | VAF 6/22 reads (27%) | catalogued as COSV59452449; called by muse, mutect2
- ANKFY1 | c.737C>A p.P246H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100493137; called by muse, varscan2
- ANKFY1 | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as rs776106549; called by muse, mutect2, varscan2
- ANKLE1 | c.967G>A p.A323T (on ENST00000394458; = p.A269T on NM_152363.6) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.105); catalogued as rs1352533232; called by muse, mutect2, varscan2
- ANKRD11 | c.5759C>T p.T1920M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); catalogued as COSV56360399; called by muse, mutect2, varscan2
- ANKRD13C | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs761816981, COSV52031716; called by muse, mutect2, varscan2
- ANKRD17 | c.5546C>T p.A1849V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as COSV58220811; called by muse, mutect2, varscan2
- ANKRD17 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV58216390; called by muse, mutect2, varscan2
- ANKRD26 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV65779028; called by muse, mutect2, varscan2
- ANKS6 | c.2171C>T p.S724F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781513591; called by muse, mutect2, varscan2
- ANO3 | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs942059529; called by muse, mutect2, varscan2
- ANXA11 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 12/19 reads (63%) | catalogued as rs541812422; called by muse, mutect2, varscan2
- ANXA2 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.962); catalogued as COSV60318194; called by muse, mutect2, varscan2
- AOC1 | c.2146G>A p.V716M | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs199683372; called by muse, mutect2, varscan2
- AP1B1 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779869503, COSV58023741; called by muse, mutect2, varscan2
- AP2A2 | c.401G>A p.C134Y | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1253105719; called by muse, mutect2, varscan2
- AP2B1 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs1280937938; called by muse, mutect2, varscan2
- AP2B1 | c.1499A>G p.Q500R | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as rs1567880561; called by muse, mutect2, varscan2
- AP5B1 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1450802231; called by muse, mutect2, varscan2
- AP5Z1 | c.815C>A p.S272Y | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs745607941; called by mutect2, varscan2
- AP5Z1 | c.1660C>T p.Q554* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as rs772628303; called by muse, mutect2, varscan2
- AP5Z1 | c.2242C>T p.R748C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs754070937, COSV62243015; called by muse, mutect2, varscan2
- APLF | c.810G>A p.M270I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100376244; called by muse, mutect2
- APLP2 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199824852, COSV53839441; called by muse, mutect2, varscan2
- APOA4 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as rs757539189, COSV63360643; called by mutect2, varscan2
- APOB | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs61742990; ClinVar: uncertain significance; called by mutect2, varscan2
- APOBR | c.1589C>T p.A530V (on ENST00000431282; = p.A539V on NM_018690.4) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.344); catalogued as rs777439097, COSV60493752; called by muse, mutect2, varscan2
- APOOL | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.758); catalogued as COSV64271578; called by muse, mutect2, varscan2
- APPL2 | c.1978G>A p.A660T | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as rs367929771; called by muse, mutect2, varscan2
- AQP1 | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs760251239; called by muse, mutect2, varscan2
- AQP7 | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs760732558; called by muse, varscan2
- AQR | c.3620T>C p.V1207A | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV50044431; called by muse, mutect2, varscan2
- AR | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as CM0910153; called by muse, mutect2, varscan2
- ARAP1 | c.2636C>T p.A879V (on ENST00000393609 / NM_001040118.2; = p.A634V on NM_015242.4) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as COSV61989478; called by muse, mutect2, varscan2
- ARAP3 | c.1671G>A p.Q557= | Splice Region (SNP) | VAF 20/59 reads (34%) | catalogued as COSV99499509; called by muse, mutect2, varscan2
- AREG | c.334dup p.Q112Pfs*7 | Frame Shift Ins (INS) | VAF 52/204 reads (25%) | catalogued as rs757742243; called by mutect2, varscan2
- ARHGAP11A | c.2723G>T p.C908F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as rs755335536; called by muse, mutect2, varscan2
- ARHGAP19 | c.68G>A p.C23Y | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.997); catalogued as rs1474727519; called by muse, mutect2, varscan2
- ARHGAP22 | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.616); catalogued as COSV50957442; called by muse, mutect2, varscan2
- ARHGAP29 | c.2191A>G p.I731V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as rs1415505877; called by muse, varscan2
- ARHGAP29 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs746453594, COSV53109176; called by muse, mutect2, varscan2
- ARHGAP32 | c.5657G>T p.R1886M (on ENST00000310343 / NM_001378025.1; = p.R1537M on NM_014715.4) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV59855664; called by muse, mutect2, varscan2
- ARHGAP35 | c.2587C>T p.R863C | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68330957; called by muse, mutect2, varscan2
- ARHGAP5 | c.3535G>A p.E1179K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.358); catalogued as COSV61535599; called by muse, mutect2, varscan2
- ARHGEF1 | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs781793791; called by muse, mutect2, varscan2
- ARHGEF10 | c.4022G>A p.R1341H (on ENST00000398564; = p.R1316H on NM_014629.4) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1232283984; called by muse, mutect2
- ARHGEF10L | c.2426G>A p.C809Y | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs978483235; called by muse, mutect2, varscan2
- ARHGEF11 | c.4235G>A p.R1412H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs201607774, COSV59356227; called by muse, mutect2, varscan2
- ARHGEF12 | c.1736A>G p.K579R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs1169256443; called by muse, mutect2, varscan2
- ARHGEF18 | c.2153G>T p.G718V (on ENST00000359920 / NM_001130955.2; = p.G614V on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100150161; called by muse, mutect2, varscan2
- ARHGEF26 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV62847241; called by muse, mutect2, varscan2
- ARHGEF28 | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs767003403; called by muse, mutect2, varscan2
- ARID1B | c.4532C>T p.S1511L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.091); catalogued as rs867707366, COSV51683601; called by muse, mutect2
- ARMC5 | c.2629C>T p.R877W | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs762770267; called by muse, varscan2
- ARMC7 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as rs771127100; called by muse, varscan2
- ARMCX1 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.899); catalogued as rs782474211; called by muse, mutect2, varscan2
- ARMCX2 | c.1397A>G p.Q466R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100167982; called by muse, mutect2, varscan2
- ARNT2 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57583204, COSV57588036; called by muse, mutect2, varscan2
- ARRB2 | c.263T>C p.F88S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV99347331; called by muse, mutect2
- ARSL | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV66965327; called by muse, mutect2, varscan2
- ARSL | c.331C>A p.R111S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.929); catalogued as COSV101140565; called by muse, mutect2, varscan2
- ASB1 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs1559413410, COSV52826874; called by muse, mutect2, varscan2
- ASB2 | c.56C>A p.P19H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs777974246; called by muse, mutect2, varscan2
- ASCC2 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as rs1343717361; called by muse, mutect2, varscan2
- ASCC3 | c.4738G>A p.A1580T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100976716; called by muse, mutect2, varscan2
- ASF1B | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as COSV99654462; called by muse, mutect2, varscan2
- ASIC3 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs150230080; called by muse, mutect2, varscan2
- ASPM | c.4658C>T p.A1553V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.222); catalogued as COSV99660004; called by muse, mutect2, varscan2
- ASTN1 | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.801); catalogued as COSV56063286; called by muse, mutect2, varscan2
- ASTN2 | c.3712C>T p.H1238Y (on ENST00000313400 / NM_001365069.1; = p.H1187Y on NM_014010.5) | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (1); PolyPhen possibly damaging (0.838); catalogued as COSV55998602; called by muse, mutect2, varscan2
- ASXL2 | c.437C>A p.S146* | Nonsense Mutation (SNP) | VAF 9/88 reads (10%) | catalogued as COSV55469588; called by mutect2, varscan2
- ATAD3A | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1272635218; called by muse, mutect2, varscan2
- ATAD3A | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.37); catalogued as COSV59235738; called by muse, varscan2
- ATM | c.7144G>T p.G2382* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as COSV53745741; called by muse, mutect2, varscan2
- ATP10A | c.4131G>A p.M1377I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV63515589; called by muse, mutect2, varscan2
- ATP10A | c.1981C>T p.P661S | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1471151044; called by muse, varscan2
- ATP10A | c.1507C>T p.R503W | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as rs759620725, COSV63516659; called by muse, mutect2, varscan2
- ATP10D | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs760805456, COSV56703377; called by muse, mutect2, varscan2
- ATP11C | c.2400G>A p.Q800= | Splice Region (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100557608; called by muse, mutect2, varscan2
- ATP11C | c.2309G>T p.S770I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV59574415; called by muse, mutect2, varscan2
- ATP11C | c.1779G>T p.M593I | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV104403929, COSV59566619; called by muse, mutect2, varscan2
- ATP12A | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755893211, COSV54517968; called by muse, mutect2, varscan2
- ATP1A1 | c.2124G>A p.Q708= | Splice Region (SNP) | VAF 8/41 reads (20%) | catalogued as rs902103517; called by muse, mutect2, varscan2
- ATP2A3 | c.1767G>A p.T589= | Splice Region (SNP) | VAF 13/48 reads (27%) | catalogued as rs763834422; called by muse, mutect2, varscan2
- ATP2B2 | c.3089C>T p.A1030V (on ENST00000352432; = p.A996V on NM_001683.5) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.341); catalogued as COSV59495115; called by muse, mutect2, varscan2
- ATP2B2 | c.1729C>T p.R577C (on ENST00000352432; = p.R543C on NM_001683.5) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1360871132, COSV59507425; called by muse, mutect2, varscan2
- ATP2B3 | c.1774G>T p.G592C | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54850485; called by mutect2, varscan2
- ATP2B4 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs754998537; called by muse, mutect2, varscan2
- ATP2C2 | c.356T>C p.L119P | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1283553165; called by muse, mutect2, varscan2
- ATP7B | c.1944G>A p.K648= | Splice Region (SNP) | VAF 19/85 reads (22%) | catalogued as rs1302960255; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP8B2 | c.2979G>T p.Q993H (on ENST00000672630; = p.Q960H on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100528002; called by muse, mutect2, varscan2
- ATP9B | c.1315A>G p.M439V | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1383384545; called by muse, mutect2, varscan2
- ATRIP | c.1292G>A p.C431Y | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as rs1173961216; called by muse, mutect2, varscan2
- ATRNL1 | c.1888G>A p.G630R | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV61796035, COSV61813253; called by muse, mutect2, varscan2
- ATRX | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1557140467, COSV64885273; called by muse, mutect2, varscan2
- ATXN2L | c.2810G>A p.S937N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.549); catalogued as rs763039872; called by muse, mutect2, varscan2
- ATXN7L2 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.022); catalogued as rs1016972776, COSV60206049; called by muse, mutect2, varscan2
- AVPR1A | c.1009G>T p.G337C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs766681015; called by muse, mutect2, varscan2
- AXIN1 | c.2521C>T p.R841* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as rs370661416, COSV51993019; called by muse, mutect2, varscan2
- AXIN1 | c.926G>A p.G309D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1267777388, COSV99250023; called by muse, mutect2, varscan2
- AXIN2 | c.1649A>G p.Y550C | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs1567755448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AZGP1 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs779480370, COSV52798203; called by muse, mutect2, varscan2
- AZIN2 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as rs1056872417, COSV99613614; called by muse, mutect2, varscan2
- B3GNT6 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.338); catalogued as rs781990020; called by muse, mutect2, varscan2
- B4GALNT1 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs139453491, COSV57541086; called by muse, mutect2, varscan2
- B4GALNT3 | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs142628932, COSV104383590; called by muse, mutect2, varscan2
- B4GALNT4 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs145647906; called by muse, mutect2, varscan2
- B4GALT3 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV60527734, COSV60527968; called by muse, mutect2, varscan2
- B9D2 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs149500212; called by muse, mutect2, varscan2
- BACH2 | c.1594G>A p.G532R | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1283633800, COSV99998768, COSV99999774; called by muse, mutect2, varscan2
- BAHCC1 | c.7856C>T p.A2619V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555660110; called by muse, mutect2, varscan2
- BAIAP2 | c.544G>T p.G182C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58337775; called by muse, mutect2, varscan2
- BANF2 | c.90G>T p.E30D | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as COSV55723966; called by muse, mutect2, varscan2
- BAP1 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs758585834; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAP1 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56240125; called by muse, mutect2, varscan2
- BARHL2 | c.1016G>A p.S339N | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.758); catalogued as rs1400776065; called by muse, mutect2, varscan2
- BARX1 | c.600+2T>C p.X200_splice | Splice Site (SNP) | VAF 13/46 reads (28%) | catalogued as rs1563989608; called by muse, mutect2, varscan2
- BATF | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs145411258, COSV54375292; called by muse, mutect2, varscan2
- BAZ2A | c.3262C>T p.R1088C | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs776907008, COSV51643345; called by muse, mutect2, varscan2
- BAZ2A | c.1378G>A p.V460I | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1277339166; called by muse, varscan2
- BAZ2A | c.1336T>C p.S446P | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as COSV51640511; called by muse, varscan2
- BBOF1 | c.1585T>G p.F529V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.024); catalogued as rs747524760; called by muse, mutect2, varscan2
- BBS9 | c.458G>A p.C153Y | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV54163066; called by muse, mutect2, varscan2
- BBX | c.2354C>T p.A785V (on ENST00000325805 / NM_001142568.3; = p.A755V on NM_020235.7) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as COSV57880806; called by muse, mutect2, varscan2
- BCAM | c.1763+1G>A p.X588_splice | Splice Site (SNP) | VAF 13/32 reads (41%) | catalogued as rs1230351368; called by muse, mutect2, varscan2
- BCAS4 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.876); catalogued as rs142613237; called by muse, varscan2
- BCAS4 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs371799931; called by muse, varscan2
- BCHE | c.401dup p.N134Kfs*24 | Frame Shift Ins (INS) | VAF 10/45 reads (22%) | catalogued as rs764588882; called by mutect2, pindel, varscan2
- BCL11B | c.2556G>T p.E852D (on ENST00000357195 / NM_001282237.2; = p.E781D on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV61733536; called by muse, mutect2, varscan2
- BCL2L13 | c.1220C>T p.T407M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1010026322; called by muse, varscan2
- BCL9L | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761151862; called by muse, varscan2
- BCL9L | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV58319675; called by muse, mutect2, varscan2
- BCLAF3 | c.1046G>A p.S349N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.439); catalogued as rs780717866; called by muse, mutect2, varscan2
- BCORL1 | c.5018G>T p.G1673V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.297); catalogued as COSV54403242; called by muse, mutect2, varscan2
- BDKRB1 | c.972G>A p.W324* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as rs1253625236, COSV53705894; called by muse, mutect2, varscan2
- BEGAIN | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.528); catalogued as rs751931340; called by muse, mutect2
- BICDL1 | c.1355A>G p.D452G | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs1188553022; called by muse, mutect2, varscan2
- BID | c.446C>T p.P149L (on ENST00000317361 / NM_197966.2; = p.P103L on NM_001196.4) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as rs575351241; called by muse, mutect2, varscan2
- BIRC6 | c.8222C>T p.A2741V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1165698520; called by muse, mutect2, varscan2
- BIRC6 | c.13007G>T p.S4336I | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.361); catalogued as COSV70195106; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.019); catalogued as rs145982160; called by mutect2, varscan2
- BLCAP | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.491); catalogued as rs1470854314, COSV50351734; called by muse, mutect2, varscan2
- BLMH | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1480557860, COSV55585417; called by muse, mutect2, varscan2
- BLNK | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs201861123; called by muse, mutect2, varscan2
- BMERB1 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs571669961; called by muse, mutect2, varscan2
- BMP1 | c.2237G>A p.G746D | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.259); catalogued as rs868091508; called by muse, mutect2, varscan2
- BMP3 | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51083544; called by muse, mutect2, varscan2
- BMP5 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 39/118 reads (33%) | catalogued as rs550837639, COSV63700675; called by muse, mutect2, varscan2
- BMS1 | c.2443C>T p.P815S | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs1296260140, COSV65735241; called by muse, varscan2
- BNC2 | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as rs1296819700, COSV101033244; called by muse, mutect2, varscan2
- BNIPL | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0.009); catalogued as COSV54847381; called by muse, mutect2, varscan2
- BOC | c.2961G>A p.T987= | Splice Region (SNP) | VAF 21/59 reads (36%) | catalogued as COSV56355161; called by muse, mutect2, varscan2
- BOD1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as rs747435012, COSV99603561; called by muse, mutect2, varscan2
- BOD1L1 | c.7190G>T p.G2397V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs1163273823; called by muse, varscan2
- BOD1L1 | c.1275G>T p.E425D | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.611); catalogued as COSV50019462; called by muse, mutect2, varscan2
- BOLA1 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs1480167110, COSV64967639; called by mutect2, varscan2
- BPGM | c.706G>T p.G236C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100790207; called by muse, varscan2
- BPIFB2 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV50070404; called by muse, mutect2, varscan2
- BRAP | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs745860025, COSV100554089; called by muse, mutect2, varscan2
- BRCA2 | c.1963C>A p.P655T | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.487); catalogued as rs1566225847, COSV66457241; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD4 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs771383580, COSV54591314; called by muse, varscan2
- BRINP2 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.028); catalogued as rs752251952; called by muse, mutect2, varscan2
- BRINP2 | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs867769568, COSV64179690; called by muse, mutect2, varscan2
- BRSK1 | c.1762C>T p.P588S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV100474538; called by muse, mutect2, varscan2
- BRWD3 | c.5356C>T p.R1786C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1158391847, COSV64746176; called by muse, mutect2, varscan2
- BRWD3 | c.3144G>T p.W1048C | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64754557; called by muse, mutect2, varscan2
- BSN | c.9437G>A p.R3146H | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs376914459; called by muse, mutect2, varscan2
- BSND | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.915); catalogued as rs982775621; called by muse, mutect2, varscan2
- BSND | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs757283527; called by muse, mutect2, varscan2
- BTBD11 | c.1796C>T p.T599I (on ENST00000280758 / NM_001018072.2; = p.T136I on NM_001017523.2) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs1451160930; called by muse, mutect2, varscan2
- BTBD16 | c.18G>T p.T6= | Splice Region (SNP) | VAF 41/134 reads (31%) | catalogued as rs756908935, COSV53266599; called by muse, mutect2, varscan2
- BTBD2 | c.1139T>C p.V380A | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.619); catalogued as rs751939717; called by muse, mutect2, varscan2
- BTBD2 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1438437676, COSV99724757; called by muse, mutect2, varscan2
- BTBD8 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100730359; called by muse, mutect2, varscan2
- BUB1 | c.1882G>A p.V628M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs1413112537; called by muse, mutect2, varscan2
- BUD13 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as rs149005278; called by muse, mutect2, varscan2
- BUD13 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV52767086; called by muse, mutect2, varscan2
- C10orf71 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as rs1261184666; called by muse, mutect2, varscan2
- C12orf42 | c.323T>C p.I108T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1555250555; called by muse, mutect2, varscan2
- C15orf39 | c.2821A>G p.T941A | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.047); catalogued as rs765791733; called by mutect2, varscan2
- C16orf72 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs1314158263; called by muse, mutect2, varscan2
- C16orf86 | c.796C>T p.L266F | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs749404349, COSV99708200; called by muse, mutect2, varscan2
- C16orf90 | c.233T>C p.L78P (on ENST00000399645 / NM_001353385.2; = p.L69P on NM_001080524.2) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV68714646; called by muse, mutect2, varscan2
- C17orf49 | c.383del p.G128Vfs*4 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs1381375195; called by mutect2, pindel, varscan2
- C18orf32 | c.110C>A p.P37H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs11537626; called by muse, mutect2, varscan2
- C19orf44 | c.1316G>A p.S439N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.153); catalogued as COSV55610521, COSV55613411; called by muse, mutect2, varscan2
- C19orf57 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.1); catalogued as COSV60968667; called by muse, mutect2, varscan2
- C1QBP | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.107); catalogued as rs115819590; called by muse, mutect2, varscan2
- C1QC | c.251C>A p.P84H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs765611134; called by mutect2, varscan2
- C1RL | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756055186; called by muse, mutect2, varscan2
- C1orf116 | c.929G>A p.S310N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1558043669; called by muse, mutect2, varscan2
- C1orf174 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.359); catalogued as rs1318233337; called by muse, mutect2, varscan2
- C20orf194 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs201615027, COSV52692875; called by muse, varscan2
- C2CD5 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV61723734; called by muse, mutect2, varscan2
- C2orf73 | c.687G>T p.Q229H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV100471395; called by muse, mutect2, varscan2
- C2orf80 | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100378673; called by muse, mutect2, varscan2
- C3AR1 | c.1213C>A p.P405T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as rs1338125145, COSV99368282; called by muse, mutect2, varscan2
- C3orf20 | c.1145G>A p.G382D | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1320629742; called by muse, mutect2, varscan2
- C4BPB | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 35/121 reads (29%) | catalogued as rs754051271, COSV54690807; called by muse, mutect2, varscan2
- C5AR2 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs764126566, COSV57256396; called by muse, varscan2
- C6orf89 | c.857G>A p.G286D (on ENST00000373685; = p.G293D on NM_152734.4) | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs748230664; called by muse, mutect2, varscan2
- C7orf33 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.017); catalogued as rs1407256984; called by muse, mutect2, varscan2
- C9orf43 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs148905915, COSV55914311; called by muse, mutect2, varscan2
- C9orf43 | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as rs756135659; called by muse, mutect2, varscan2
- CA12 | c.557T>C p.I186T | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375002808; called by muse, mutect2, varscan2
- CA2 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762201348; called by mutect2, varscan2
- CAB39 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV51477713; called by muse, mutect2, varscan2
- CABIN1 | c.2740C>T p.R914* | Nonsense Mutation (SNP) | VAF 24/83 reads (29%) | catalogued as rs750920866, COSV99573606; called by muse, mutect2, varscan2
- CACNA1A | c.4201C>T p.L1401F | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs766816378; called by muse, mutect2, varscan2
- CACNA1B | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.04); catalogued as rs200683902; called by muse, mutect2, varscan2
- CACNA1C | c.4819C>T p.P1607S | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs745938574, CM139929, COSV59714998; called by muse, mutect2, varscan2
- CACNA1D | c.764C>A p.P255H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99860458; called by muse, mutect2, varscan2
- CACNA1D | c.3622G>A p.E1208K (on ENST00000350061 / NM_001128840.3; = p.E1228K on NM_000720.4) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55445291; called by muse, mutect2, varscan2
- CACNA1E | c.2813G>A p.R938Q | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs762485881, COSV100706283, COSV62382855; called by muse, mutect2, varscan2
- CACNA1F | c.4792C>T p.R1598W | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs782005032; called by muse, mutect2, varscan2
- CACNA1F | c.3595C>T p.L1199F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV59903670; called by muse, mutect2, varscan2
- CACNA1F | c.508A>G p.I170V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as rs1557111168; called by muse, mutect2, varscan2
- CACNA1G | c.5357G>A p.R1786Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs369172303; called by muse, mutect2, varscan2
- CACNA1H | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs765251048; called by muse, mutect2, varscan2
- CACNA1H | c.4547C>T p.A1516V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100673764; called by muse, varscan2
- CACNA1I | c.2335C>A p.L779I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60801262; called by muse, mutect2, varscan2
- CACNA1I | c.2803dup p.R935Pfs*29 | Frame Shift Ins (INS) | VAF 9/35 reads (26%) | catalogued as rs751819797; called by mutect2, pindel, varscan2
- CACNA2D4 | c.2014C>T p.H672Y | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1282541655; called by muse, mutect2, varscan2
- CACNB2 | c.1874G>A p.R625H (on ENST00000324631 / NM_201596.3; = p.R570H on NM_000724.4) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as rs772911828, COSV99993061; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNB4 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763313869; called by muse, varscan2
- CACNG7 | c.629A>G p.Y210C | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs576059025; called by muse, mutect2, varscan2
- CACUL1 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.014); catalogued as COSV60993654, COSV60994352; called by muse, mutect2, varscan2
- CADPS2 | c.2687A>C p.Q896P | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775276661; called by muse, mutect2, varscan2
- CADPS2 | c.2186G>T p.R729M | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57352153; called by muse, mutect2, varscan2
- CAGE1 | c.2084A>G p.H695R (on ENST00000512086; = p.H559R on NM_205864.3) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57080421; called by muse, varscan2
- CAGE1 | c.1778C>T p.P593L (on ENST00000512086; = p.P457L on NM_205864.3) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376342450; called by muse, mutect2, varscan2
- CAGE1 | c.590G>A p.S197N (on ENST00000512086; = p.S61N on NM_205864.3) | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs760455037; called by muse, mutect2, varscan2
- CALCOCO1 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV50419120; called by muse, mutect2, varscan2
- CALCR | c.1346C>T p.A449V (on ENST00000649521 / NM_001164737.2; = p.A433V on NM_001742.4) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.64); catalogued as rs780358113, COSV64010215; called by muse, varscan2
- CALM3 | c.150G>T p.Q50H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.054); catalogued as COSV99355153; called by muse, mutect2, varscan2
- CAMK2D | c.404G>T p.R135M | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV99595052; called by muse, mutect2, varscan2
- CAMSAP1 | c.4253G>A p.G1418E | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs544399066; called by muse, mutect2, varscan2
- CAMSAP1 | c.3263G>A p.R1088H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs867958908; called by muse, mutect2, varscan2
- CAMTA1 | c.2734C>T p.P912S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV57908882; called by muse, mutect2, varscan2
- CAND1 | c.2906G>A p.R969Q | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV101607306; called by muse, mutect2, varscan2
- CANT1 | c.371C>T p.T124I | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1277018466; called by muse, mutect2, varscan2
- CAPN12 | c.853T>C p.W285R | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100185160; called by muse, mutect2, varscan2
- CAPN12 | c.432G>A p.W144* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV61014696; called by muse, mutect2, varscan2
- CAPN3 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs919442493, CM051871; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPS2 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs896636178; called by muse, mutect2, varscan2
- CAPZB | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.996); catalogued as rs746198763; called by muse, mutect2, varscan2
- CARMIL2 | c.359C>A p.P120H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58026401; called by muse, varscan2
- CARS2 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs988495210, COSV57289289; called by muse, mutect2, varscan2
- CASKIN2 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199947018; called by muse, varscan2
- CASP14 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.798); catalogued as COSV99692977; called by muse, mutect2
- CASP2 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1319647377; called by muse, mutect2, varscan2
- CASP8AP2 | c.5866G>A p.A1956T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0.014); catalogued as rs1283207155, COSV52749854; called by muse, mutect2, varscan2
- CAST | c.762G>T p.E254D (on ENST00000341926; = p.E337D on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.822); catalogued as COSV100352393; called by muse, mutect2, varscan2
- CASZ1 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.17); catalogued as COSV59733541; called by muse, mutect2, varscan2
- CASZ1 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV100680848; called by muse, mutect2, varscan2
- CATSPER1 | c.617A>G p.E206G | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1236786826; called by muse, mutect2, varscan2
- CATSPERB | c.1293G>A p.W431* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV56424401; called by mutect2, varscan2
- CATSPERD | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1355730634; called by muse, mutect2, varscan2
- CATSPERG | c.3364G>A p.G1122R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs376077607; called by muse, mutect2, varscan2
- CBLL1 | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs1268745728; called by muse, mutect2, varscan2
- CBLL2 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs1230861905; called by muse, mutect2, varscan2
- CC2D1A | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.051); catalogued as rs986781288; called by muse, varscan2
- CC2D1A | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as COSV58784675; called by muse, varscan2
- CC2D1B | c.6G>A p.M2I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV52561054; called by muse, varscan2
- CCAR1 | c.2615C>A p.P872H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV56273884; called by muse, mutect2
- CCBE1 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs140813794; called by muse, mutect2, varscan2
- CCDC105 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757213881, COSV52965891; called by mutect2, varscan2
- CCDC134 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as rs1193141255, COSV55387603; called by muse, mutect2, varscan2
- CCDC15 | c.2849del p.N950Ifs*17 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | catalogued as rs778259441; called by mutect2, pindel, varscan2
- CCDC170 | c.1007G>A p.G336D | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as rs766759929; called by muse, mutect2, varscan2
- CCDC180 | c.4280A>G p.K1427R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1322092587; called by muse, mutect2, varscan2
- CCDC189 | c.392G>A p.C131Y | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100079559; called by muse, mutect2, varscan2
- CCDC40 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs780647441, COSV53904438; ClinVar: uncertain significance; called by muse, varscan2
- CCDC42 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776086783, COSV99549883; called by muse, mutect2, varscan2
- CCDC51 | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.037); catalogued as rs1262299094; called by muse, mutect2, varscan2
- CCDC54 | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV53759809; called by muse, mutect2, varscan2
- CCDC6 | c.1005-1G>T p.X335_splice | Splice Site (SNP) | VAF 4/29 reads (14%) | catalogued as COSV99569495; called by muse, mutect2, varscan2
- CCDC63 | c.422T>C p.M141T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs762748497; called by muse, mutect2, varscan2
- CCDC8 | c.1234G>A p.V412I | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs752421136, COSV56773040; called by muse, mutect2, varscan2
- CCDC8 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.112); catalogued as rs1321911366; called by muse, mutect2, varscan2
- CCDC80 | c.1876C>T p.L626F | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs368208153; called by muse, mutect2, varscan2
- CCDC82 | c.446A>G p.Q149R | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.043); catalogued as COSV99567146; called by muse, mutect2, varscan2
- CCDC83 | c.836C>T p.P279L (on ENST00000342404 / NM_001286159.2; = p.P310L on NM_173556.5) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs1289744896; called by muse, mutect2, varscan2
- CCDC85A | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745437450, COSV68152669; called by muse, mutect2, varscan2
- CCDC88B | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1212959212; called by muse, mutect2, varscan2
- CCDC88C | c.3460C>T p.Q1154* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV99062334; called by muse, mutect2, varscan2
- CCDC89 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.526); catalogued as COSV57034378; called by muse, mutect2
- CCDC93 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765217420, COSV60124074; called by muse, mutect2, varscan2
- CCM2L | c.219G>T p.W73C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.964); catalogued as rs1239414385; called by muse, mutect2, varscan2
- CCN1 | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV71704327; called by muse, mutect2, varscan2
- CCN6 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM126424, COSV57891143; called by muse, mutect2, varscan2
- CCNB1 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.994); catalogued as COSV99841426; called by muse, mutect2, varscan2
- CCNB3 | c.1364C>T p.S455L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782227314, COSV52079419; called by muse, mutect2, varscan2
- CCNF | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as rs772205153, COSV53540255; called by muse, mutect2, varscan2
- CCR7 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55849457; called by muse, mutect2, varscan2
- CCR8 | c.154G>T p.G52* | Nonsense Mutation (SNP) | VAF 47/138 reads (34%) | catalogued as COSV58336789; called by muse, mutect2, varscan2
- CCSER1 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.271); catalogued as COSV61448592; called by muse, mutect2
- CCT8L2 | c.932G>A p.G311D | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.614); catalogued as COSV63463932; called by muse, mutect2, varscan2
- CD109 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747748880; called by muse, mutect2, varscan2
- CD22 | c.2111G>A p.C704Y | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as rs144772029; called by muse, mutect2, varscan2
- CD276 | c.1351G>A p.G451S (on ENST00000318443 / NM_001024736.2; = p.G233S on NM_025240.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.534); catalogued as rs534967569, COSV59205313; called by muse, mutect2, varscan2
- CD300LF | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as rs201675456; called by muse, mutect2, varscan2
- CD40 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1361629901, COSV100953861; called by muse, mutect2, varscan2
- CD40LG | c.749G>A p.G250D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.014); catalogued as CM960263, COSV65698387; called by muse, varscan2
- CD5L | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.649); catalogued as rs899486061, COSV63821614; called by muse, varscan2
- CD80 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as rs1250491500, COSV51802031; called by muse, mutect2, varscan2
- CD80 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs780121133, COSV99958236; called by muse, mutect2, varscan2
- CD93 | c.144G>T p.E48D | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV55663706; called by muse, mutect2, varscan2
- CDC16 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs746050870; called by muse, mutect2, varscan2
- CDC16 | c.814A>T p.I272L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV52959098; called by muse, mutect2, varscan2
- CDC37L1 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs185508868; called by muse, mutect2, varscan2
- CDC42BPA | c.4870C>T p.P1624S (on ENST00000334218 / NM_001366019.2; = p.P1611S on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs779954841; called by muse, mutect2, varscan2
- CDC42BPB | c.3152G>A p.R1051Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755257364, COSV100775264; called by mutect2, varscan2
- CDC7 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1224227390; called by muse, mutect2, varscan2
- CDCA7L | c.681G>A p.M227I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV100651237; called by muse, mutect2, varscan2
- CDCA8 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs752774201; called by muse, mutect2, varscan2
- CDH10 | c.1577del p.F526Sfs*3 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as rs1209448007; called by mutect2, varscan2
- CDH12 | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1269036740; called by muse, mutect2, varscan2
- CDH19 | c.2197C>A p.L733M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50962151; called by muse, mutect2, varscan2
- CDH23 | c.3385G>A p.A1129T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.181); catalogued as rs746708121; called by muse, varscan2
- CDH23 | c.9151C>T p.Q3051* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV56487610; called by muse, mutect2, varscan2
- CDH24 | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV99943309; called by muse, mutect2
- CDH3 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.554); catalogued as COSV50556828; called by muse, mutect2, varscan2
- CDH3 | c.2191C>T p.R731C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs139153891; called by mutect2, varscan2
- CDH4 | c.2215C>T p.L739F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV64643101; called by muse, mutect2, varscan2
- CDH8 | c.272C>A p.P91H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV54863506, COSV54874111; called by muse, mutect2, varscan2
- CDH9 | c.857A>G p.H286R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.09); catalogued as rs755158803; called by muse, mutect2, varscan2
- CDHR2 | c.3086G>A p.G1029D | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.146); catalogued as rs778532418; called by muse, mutect2, varscan2
- CDK10 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs748526308, COSV58416140; called by muse, mutect2, varscan2
- CDK13 | c.1826C>A p.P609Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as COSV51696109; called by muse, mutect2
- CDK14 | c.662T>C p.M221T (on ENST00000380050 / NM_001287135.2; = p.M203T on NM_012395.3) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56024915; called by muse, mutect2, varscan2
- CDK19 | c.361A>G p.M121V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1275907568; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5680T>C p.*1894Rext*102 | Nonstop Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as rs758937704; called by muse, mutect2, varscan2
- CDON | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1247152221; called by muse, mutect2, varscan2
- CDRT1 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375199803; called by muse, varscan2
- CDT1 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1202670110; called by muse, mutect2, varscan2
- CDYL | c.763G>T p.G255W (on ENST00000328908 / NM_001368125.1; = p.G201W on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV59359826, COSV59361591; called by muse, mutect2, varscan2
- CEACAM1 | c.1007C>T p.T336I | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as rs758465713; called by muse, mutect2, varscan2
- CEL | c.1429C>T p.R477W (on ENST00000673714; = p.R474W on NM_001807.6) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.049); catalogued as rs749712301, COSV60826388; called by muse, mutect2, varscan2
- CELA3A | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs545849491; called by muse, mutect2, varscan2
- CELA3B | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as rs755064029; called by muse, mutect2, varscan2
- CELF4 | c.1027G>T p.G343C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.858); catalogued as rs773175289; called by muse, mutect2, varscan2
- CELF5 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99486179; called by muse, mutect2, varscan2
- CELF6 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.196); catalogued as rs760953520, COSV99764073; called by mutect2, varscan2
- CELSR1 | c.5964+2T>C p.X1988_splice | Splice Site (SNP) | VAF 12/40 reads (30%) | catalogued as rs1245329227; called by muse, mutect2, varscan2
- CELSR1 | c.5087G>A p.G1696D | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs773693439; called by muse, mutect2, varscan2
- CELSR3 | c.6097G>A p.G2033R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99374201; called by muse, mutect2, varscan2
- CELSR3 | c.5003C>T p.T1668M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs889878818; called by muse, mutect2, varscan2
- CEMIP | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as rs773990711, COSV54996628; called by muse, mutect2, varscan2
- CEMIP2 | c.3446G>A p.C1149Y | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1192866511; called by muse, mutect2, varscan2
- CENPE | c.1982C>T p.T661I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs1439196761; called by muse, mutect2, varscan2
- CENPO | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs574000727, COSV53229527; called by muse, varscan2
- CEP128 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.242); catalogued as rs779458155, COSV53673343; called by muse, mutect2, varscan2
- CEP152 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as rs890100400, COSV57857674; called by muse, mutect2, varscan2
- CEP164 | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs1461354410; called by muse, varscan2
- CEP192 | c.7249C>T p.R2417* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as rs149673520; called by muse, mutect2, varscan2
- CEP72 | c.785G>A p.G262E | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.823); catalogued as rs768607281; called by mutect2, varscan2
- CERK | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs747446564, COSV99348640; called by muse, mutect2, varscan2
- CES2 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs139864573; called by muse, mutect2, varscan2
- CES2 | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.036); catalogued as rs141601821; called by muse, mutect2, varscan2
- CES2 | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as rs771819448; called by muse, mutect2
- CES3 | c.1601G>C p.R534P | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.828); catalogued as rs144166705, COSV100310058, COSV57592909; called by muse, mutect2, varscan2
- CFAP20 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs1268119185; called by muse, mutect2, varscan2
- CFAP221 | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as rs140592618; called by muse, mutect2, varscan2
- CFAP53 | c.1016A>G p.Q339R | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as rs1470295882; called by muse, mutect2, varscan2
- CFAP57 | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV100994021; called by muse, mutect2, varscan2
- CFAP74 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs767905405; called by muse, mutect2, varscan2
- CFAP97 | c.201G>T p.K67N | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as COSV99703398; called by muse, mutect2, varscan2
- CFC1 | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99383472; called by muse, mutect2, varscan2
- CFDP1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52210015; called by muse, mutect2, varscan2
- CFH | c.1240G>A p.V414I | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.172); catalogued as rs761008984, COSV100661304; called by muse, mutect2, varscan2
- CFH | c.2058G>A p.V686= | Splice Region (SNP) | VAF 10/56 reads (18%) | catalogued as rs541280297; called by muse, mutect2, varscan2
- CFH | c.3680C>A p.T1227N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as CM1512058; called by muse, mutect2, varscan2
- CFP | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1427476310; called by muse, mutect2, varscan2
- CHD6 | c.6460G>A p.A2154T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs200381276, COSV64692603; called by muse, mutect2, varscan2
- CHD6 | c.1338G>A p.W446* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100498501; called by muse, mutect2, varscan2
- CHD7 | c.1135C>T p.Q379* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as CM126598; called by muse, mutect2, varscan2
- CHD7 | c.7009C>T p.R2337C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs765610436, COSV71111964; called by muse, mutect2, varscan2
- CHD8 | c.1520C>A p.A507D (on ENST00000646647 / NM_001170629.2; = p.A228D on NM_020920.4) | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.065); catalogued as COSV67870682; called by muse, mutect2, varscan2
- CHD9 | c.4822G>A p.E1608K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs866311297; called by muse, mutect2, varscan2
- CHD9 | c.5108C>T p.A1703V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs1428337275; called by muse, mutect2, varscan2
- CHEK2 | c.919G>A p.A307T (on ENST00000382580 / NM_001005735.2; = p.A264T on NM_007194.4) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs752493299; called by muse, mutect2, varscan2
- CHEK2 | c.512C>A p.P171Q (on ENST00000382580 / NM_001005735.2; = p.P128Q on NM_007194.4) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.242); catalogued as COSV60426648; called by muse, mutect2, varscan2
- CHIA | c.417G>A p.W139* (on ENST00000343320; = p.W31* on NM_021797.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 30/78 reads (38%) | catalogued as rs1051094185, COSV100588943; called by muse, mutect2, varscan2
- CHN1 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.511); catalogued as COSV55035464; called by muse, mutect2, varscan2
- CHPT1 | c.485del p.F162Sfs*23 | Frame Shift Del (DEL) | VAF 41/135 reads (30%) | catalogued as rs755424899; called by mutect2, varscan2
- CHRNA4 | c.1825G>A p.V609I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs201168195; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRNA9 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370290456; called by muse, mutect2, varscan2
- CHTF18 | c.2650G>A p.E884K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs533449448; called by muse, mutect2, varscan2
- CIB3 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.802); catalogued as rs200570024; called by muse, mutect2, varscan2
- CIC | c.3041C>T p.A1014V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as rs780624177, COSV50583284, COSV50678188; called by mutect2, varscan2
- CILP2 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.176); catalogued as rs774293541; called by muse, mutect2, varscan2
- CIPC | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.69); catalogued as rs201665496, COSV62377023; called by muse, mutect2, varscan2
- CIT | c.5279C>T p.T1760M | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs180716474; ClinVar: uncertain significance; called by muse, varscan2
- CIT | c.3952G>A p.A1318T | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.383); catalogued as rs767158335; called by muse, mutect2, varscan2
- CKAP2 | c.1683T>A p.D561E (on ENST00000378037 / NM_001098525.2; = p.D560E on NM_018204.5) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs755154829; called by muse, mutect2, varscan2
- CLASP1 | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs771121083; called by muse, mutect2, varscan2
- CLASRP | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.03); catalogued as rs1181802908, COSV55515060; called by muse, mutect2, varscan2
- CLBA1 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs536323271; called by mutect2, varscan2
- CLCA1 | c.2456C>T p.A819V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV52325608; called by muse, mutect2, varscan2
- CLCN7 | c.2284C>T p.R762W | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1490598538, CM099589; called by muse, mutect2, varscan2
- CLCNKA | c.1408G>T p.G470W | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58890657; called by muse, mutect2, varscan2
- CLDN16 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.867); catalogued as CM085325; called by muse, mutect2
- CLDN6 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); catalogued as rs749694613; called by muse, mutect2, varscan2
- CLDND1 | c.613C>A p.P205T | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57860103; called by muse, mutect2, varscan2
- CLEC4A | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | catalogued as rs764432384, COSV57561593; called by muse, mutect2, varscan2
- CLEC4M | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs567294021; called by muse, mutect2, varscan2
- CLEC4M | c.1047C>T p.P349= | Splice Region (SNP) | VAF 6/38 reads (16%) | catalogued as COSV50221799; called by muse, mutect2, varscan2
- CLIP1 | c.3253G>A p.A1085T (on ENST00000620786 / NM_001247997.1; = p.A1074T on NM_002956.2) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs574633657; called by muse, mutect2, varscan2
- CLIP2 | c.1319G>T p.R440M | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56275667; called by mutect2, varscan2
- CLSTN2 | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs764474827; called by muse, mutect2, varscan2
- CLSTN3 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1330525617; called by muse, mutect2, varscan2
- CLUH | c.1366G>A p.V456I (on ENST00000435359; = p.V494I on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs778439361; called by mutect2, varscan2
- CMIP | c.1561G>A p.G521S (on ENST00000537098 / NM_198390.2; = p.G427S on NM_030629.3) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as rs374999407; called by muse, mutect2, varscan2
- CMKLR1 | c.275T>C p.L92P (on ENST00000312143 / NM_001142344.2; = p.L90P on NM_004072.3) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100379185; called by muse, mutect2, varscan2
- CMSS1 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV70435643; called by muse, mutect2, varscan2
- CMTM3 | c.148-1G>T p.X50_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as COSV62680334; called by muse, mutect2, varscan2
- CNBD2 | c.1362G>T p.K454N (on ENST00000373973 / NM_001365709.1; = p.K450N on NM_080834.4) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV62587389; called by muse, mutect2, varscan2
- CNDP1 | c.1250C>A p.P417Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144587048, COSV100722249, COSV62595239; called by muse, mutect2, varscan2
- CNGA2 | c.372C>T p.T124= | Splice Region (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100323495; called by muse, mutect2, varscan2
- CNGA3 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775153981; called by muse, mutect2, varscan2
- CNGB3 | c.1946A>G p.K649R | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as rs1330320172; called by muse, mutect2, varscan2
- CNGB3 | c.658C>A p.L220M | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100181046; called by muse, mutect2
- CNKSR2 | c.3032G>A p.S1011N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs904272904, COSV101069923; called by muse, mutect2, varscan2
- CNNM2 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as rs1164136549, COSV64000795; called by muse, mutect2, varscan2
- CNNM3 | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as rs767042346; called by mutect2, varscan2
- CNOT10 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs755586827; called by mutect2, varscan2
- CNOT4 | c.1723C>T p.P575S (on ENST00000541284 / NM_001190850.1; = p.P572S on NM_001190849.2) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs11976681; called by muse, mutect2, varscan2
- CNRIP1 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1384585047; called by muse, mutect2, varscan2
- CNTD1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.366); catalogued as COSV100162105; called by muse, mutect2, varscan2
- CNTN2 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs778415451, COSV100085119; called by muse, mutect2, varscan2
- CNTN4 | c.2204A>G p.Y735C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179501584; called by muse, mutect2, varscan2
- CNTN4 | c.2332G>T p.G778C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746683419; called by muse, mutect2, varscan2
- CNTN5 | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54344302, COSV99677154; called by muse, mutect2, varscan2
- CNTNAP1 | c.3677G>A p.R1226Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs1481806507, COSV52849055; called by muse, mutect2, varscan2
- CNTNAP3 | c.3046G>T p.E1016* | Nonsense Mutation (SNP) | VAF 81/1035 reads (8%) | catalogued as COSV52666338; called by muse, mutect2
- CNTNAP5 | c.3107C>T p.S1036F | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV70478224; called by muse, mutect2, varscan2
- CNTRL | c.3649G>T p.D1217Y | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV99443209; called by muse, mutect2, varscan2
- COBLL1 | c.1595T>C p.L532P (on ENST00000392717; = p.L494P on NM_014900.5) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.559); catalogued as rs755881283; called by muse, mutect2, varscan2
- COCH | c.1042G>A p.E348K (on ENST00000216361 / NM_001347720.1; = p.E283K on NM_004086.3) | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs1224796113, COSV53551713; called by muse, mutect2, varscan2
- COG4 | c.1505G>A p.R502Q | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs190357875; called by muse, mutect2, varscan2
- COL11A1 | c.4159G>T p.G1387C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100615438; called by muse, varscan2
- COL11A1 | c.4141-1G>A p.X1381_splice | Splice Site (SNP) | VAF 14/63 reads (22%) | catalogued as COSV62195939; called by muse, varscan2
- COL11A1 | c.3455C>T p.P1152L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV62194966; called by muse, mutect2, varscan2
- COL11A1 | c.3356C>T p.A1119V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV62200452; called by muse, mutect2, varscan2
- COL11A1 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs995254814, COSV62175243; called by muse, mutect2, varscan2
- COL11A1 | c.1100G>A p.G367D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.157); catalogued as rs1402186540, COSV100617628, COSV62189962, COSV62201705; called by muse, mutect2, varscan2
- COL12A1 | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.888); catalogued as COSV59392651; called by muse, mutect2, varscan2
- COL14A1 | c.2531G>A p.R844Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as rs755318491, COSV52854154; called by muse, mutect2, varscan2
- COL15A1 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373530299; called by muse, mutect2, varscan2
- COL15A1 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV66645465; called by muse, varscan2
- COL17A1 | c.3535C>T p.P1179S | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.963); catalogued as COSV62226995; called by muse, mutect2, varscan2
- COL22A1 | c.4840G>A p.A1614T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs758961090; called by mutect2, varscan2
- COL24A1 | c.3445G>T p.G1149* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as rs768569706; called by muse, mutect2, varscan2
- COL24A1 | c.2923G>A p.G975S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762052966, COSV65315583; called by muse, mutect2, varscan2
- COL24A1 | c.1604C>A p.P535H | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs747570012, COSV100993839; called by muse, mutect2, varscan2
- COL25A1 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as rs1030036795, COSV101211381; called by muse, mutect2, varscan2
- COL2A1 | c.4448C>T p.P1483L | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as rs376442872; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- COL3A1 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.328); catalogued as rs187907868, COSV58584690, COSV58597018; called by muse, mutect2, varscan2
- COL3A1 | c.2822C>T p.P941L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs747784033; called by mutect2, varscan2
- COL4A3 | c.2452G>T p.G818* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as rs868002181, CM1312534; called by muse, mutect2, varscan2
- COL4A4 | c.3151G>A p.G1051S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161763333, CM143848, COSV100307217, COSV61632650, COSV61635540; called by muse, mutect2, varscan2
- COL4A4 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100307728; called by muse, mutect2, varscan2
- COL4A6 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766762324; called by muse, mutect2, varscan2
- COL5A3 | c.964-2A>G p.X322_splice | Splice Site (SNP) | VAF 15/71 reads (21%) | catalogued as rs1417086722; called by muse, mutect2, varscan2
- COL6A1 | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777067695; called by muse, mutect2, varscan2
- COL7A1 | c.8320G>A p.A2774T | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1447600920; called by muse, mutect2, varscan2
- COL7A1 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs757929353, COSV60403166; called by muse, mutect2, varscan2
- COL9A2 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as rs764157850, COSV65608064; called by muse, mutect2, varscan2
- COL9A2 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as rs1315693882, COSV101025669; called by muse, mutect2, varscan2
- COLEC12 | c.2209G>T p.V737L | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV101232021; called by muse, mutect2, varscan2
- COLGALT1 | c.431T>C p.M144T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV53109667; called by muse, mutect2, varscan2
- COLGALT1 | c.1636C>A p.L546M | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV53111873; called by muse, mutect2, varscan2
- COMMD2 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.012); catalogued as rs373377514; called by muse, mutect2, varscan2
- COPA | c.1102A>G p.M368V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as rs761130880; called by muse, mutect2, varscan2
- COQ2 | c.997A>G p.S333G | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as rs765629648; called by muse, mutect2, varscan2
- COQ3 | c.562A>G p.K188E | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.759); catalogued as COSV54640929; called by muse, mutect2, varscan2
- COQ6 | c.841C>A p.L281I | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53180328; called by muse, mutect2, varscan2
- CORIN | c.2271G>A p.W757* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as rs1441470742; called by muse, mutect2, varscan2
- CORIN | c.231T>A p.F77L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV56685449, COSV56695046; called by mutect2, varscan2
- CORO1A | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54630527; called by muse, mutect2, varscan2
- CP | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV52834924; called by muse, mutect2, varscan2
- CPAMD8 | c.2591G>A p.R864H (on ENST00000651564; = p.R817H on NM_015692.5) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754265681; called by muse, mutect2, varscan2
- CPAMD8 | c.1801G>A p.V601I (on ENST00000651564; = p.V554I on NM_015692.5) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV99359163; called by muse, mutect2, varscan2
- CPEB3 | c.793G>A p.G265S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.986); catalogued as rs761634354; called by muse, mutect2, varscan2
- CPED1 | c.3013G>T p.G1005C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765606406; called by muse, mutect2, varscan2
- CPNE3 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV52209423; called by muse, mutect2, varscan2
- CPNE4 | c.1124A>G p.H375R | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV101456551; called by muse, mutect2, varscan2
- CPNE9 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs772299797; called by muse, mutect2, varscan2
- CPPED1 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.313); catalogued as rs201640855; called by muse, mutect2, varscan2
- CPQ | c.521A>G p.N174S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as COSV55136748; called by muse, mutect2, varscan2
- CPSF1 | c.1589C>T p.P530L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1554865217, COSV62939130; called by muse, varscan2
- CPXM2 | c.2127G>A p.M709I | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.055); catalogued as rs771808249, COSV53862285, COSV53866923; called by muse, mutect2, varscan2
- CPXM2 | c.1804A>G p.T602A | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1292795012; called by muse, mutect2, varscan2
- CR1 | c.4954C>T p.P1652S | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0.209); catalogued as COSV100888035; called by muse, mutect2, varscan2
- CR1 | c.5374G>T p.D1792Y | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.888); catalogued as rs760180458; called by muse, mutect2, varscan2
- CRACD | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1036915077, COSV99948779; called by muse, mutect2, varscan2
- CRACD | c.2456C>T p.S819L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV51723578; called by muse, mutect2, varscan2
- CRACD | c.3179G>A p.G1060E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.748); catalogued as COSV51719093; called by muse, mutect2, varscan2
- CRB1 | c.557A>G p.E186G | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV66349483; called by muse, mutect2, varscan2
- CREB3 | c.1033dup p.L345Pfs*16 | Frame Shift Ins (INS) | VAF 6/10 reads (60%) | catalogued as rs1295156644; called by mutect2, varscan2
- CREBRF | c.956T>C p.L319P | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.474); catalogued as rs1423399878; called by muse, mutect2, varscan2
- CRHR1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1296149083, COSV99523555; called by muse, mutect2, varscan2
- CRHR2 | c.1181C>A p.P394H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59267847; called by muse, mutect2, varscan2
- CRMP1 | c.1658G>A p.R553H | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs759182182; called by muse, mutect2, varscan2
- CRY2 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs1217929651, COSV101314590; called by muse, varscan2
- CRYBG3 | c.6290A>G p.D2097G | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51712349; called by muse, mutect2
- CRYZ | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as rs368154779; called by muse, mutect2
- CSE1L | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.562); catalogued as rs778061824; called by mutect2, varscan2
- CSF1R | c.952G>T p.G318W | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV53837612; called by muse, mutect2, varscan2
- CSF2RB | c.1089G>T p.M363I | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV99454462; called by muse, mutect2, varscan2
- CSMD1 | c.8242G>T p.G2748* (on ENST00000520002; = p.G2747* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV59350588; called by muse, mutect2, varscan2
- CSMD2 | c.10304G>T p.R3435M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53923276; called by muse, mutect2, varscan2
- CSMD2 | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs772682510, COSV53944208; called by muse, mutect2, varscan2
- CSNK1A1L | c.690dup p.Q231Tfs*4 | Frame Shift Ins (INS) | VAF 18/66 reads (27%) | catalogued as rs369743261; called by mutect2, varscan2
- CSNK1D | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.796); catalogued as rs1568564548; called by muse, mutect2, varscan2
- CSNK1E | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); catalogued as rs1230602951, COSV104417268; called by muse, mutect2, varscan2
- CSNK1G1 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs145663344; called by muse, mutect2, varscan2
- CSPG4 | c.5422G>A p.A1808T | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV57893550; called by muse, mutect2, varscan2
- CSPG4 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1216817944; called by muse, mutect2, varscan2
- CSRNP3 | c.64A>G p.R22G | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.295); catalogued as rs201041137, COSV58777780; called by muse, mutect2, varscan2
- CST8 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.119); catalogued as rs1409605526; called by muse, mutect2
- CTCF | c.1555G>A p.G519R | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs911362614, COSV50472696; called by muse, mutect2, varscan2
- CTCF | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50464182; called by muse, mutect2, varscan2
- CTDP1 | c.1278G>T p.Q426H | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV99310547; called by muse, mutect2
- CTDP1 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.023); catalogued as rs948763617; called by muse, mutect2, varscan2
- CTLA4 | c.494G>A p.W165* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV55593275; called by muse, mutect2, varscan2
- CTNNA2 | c.1808C>A p.P603Q | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV58174544; called by muse, varscan2
- CTNNA2 | c.2390C>T p.A797V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100559694; called by muse, mutect2, varscan2
- CTNNA3 | c.2098G>T p.D700Y | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65528840; called by muse, mutect2, varscan2
- CTNNAL1 | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57705770; called by muse, mutect2, varscan2
- CTNND1 | c.1751G>A p.R584Q | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1486500759, COSV62385314; called by muse, mutect2, varscan2
- CTNND2 | c.1399G>A p.V467I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs760190967, COSV58877403; called by muse, mutect2, varscan2
12,439 further variants in this file (8,450 protein-altering or splice-affecting, 3,720 silent, 269 other) are not listed here.
